Somatic mutation profile of tumor specimen TCGA-R5-A804-01A (aliquot TCGA-R5-A804-01A-11D-A364-08) from TCGA case TCGA-R5-A804, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 54.8 years (20,026 days).
Specimen TCGA-R5-A804-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee24d28e-2ecb-46c3-9b38-1512e74f6617.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R5-A804-10A (Blood Derived Normal), aliquot TCGA-R5-A804-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/364f165b-b71a-4ad8-a814-c08952f202b5

The open-access MAF lists 86 somatic variants for this specimen: 62 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 23, Nonsense Mutation 8, Frame Shift Ins 1, In Frame Del 1, Splice Site 1, Splice Region 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.13450C>T p.R4484* | Nonsense Mutation (SNP) | VAF 20/105 reads (19%) | catalogued as rs587783690, CM111921, COSV56434635; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LCA5 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as rs866395428, CM155292, COSV63972189; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 18/140 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by muse, mutect2, varscan2
- RHOA | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 15/92 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs1057519953, COSV69041526, COSV69042045; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SACS | c.5629C>T p.R1877* | Nonsense Mutation (SNP) | VAF 10/128 reads (8%) | catalogued as rs761089024, CM111519, COSV66533403; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- ABCA2 | c.1800G>C p.Q600H (on ENST00000614293; = p.Q570H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV55805591, COSV99686900; called by muse, mutect2
- ACTBL2 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as COSV101379226; called by muse, mutect2
- ANKRA2 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.929); catalogued as rs577768694, COSV99706927; called by muse, mutect2
- ARID1A | c.2550T>G p.Y850* | Nonsense Mutation (SNP) | VAF 20/62 reads (32%) | catalogued as COSV100250335, COSV61388695; called by muse, mutect2, varscan2
- BAIAP3 | c.3259G>A p.V1087M | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773167930, COSV99136130; called by muse, mutect2
- BBS9 | c.809G>T p.C270F | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763742314, COSV99626047; called by muse, mutect2, varscan2
- CD1E | c.447T>G p.S149R | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV100936911; called by muse, mutect2, varscan2
- CDH1 | c.1021T>G p.Y341D | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99931250; called by muse, mutect2, varscan2
- CHD4 | c.3560G>A p.R1187Q (on ENST00000357008 / NM_001363606.2; = p.R1200Q on NM_001273.5) | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58898240; called by muse, mutect2, varscan2
- COL5A2 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs540573303; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CRACR2A | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99364582; called by muse, mutect2
- CTSE | c.1102C>T p.P368S (on ENST00000360218; = p.P363S on NM_001910.4) | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.614); catalogued as COSV100733485; called by muse, mutect2, varscan2
- EBF2 | c.351C>T p.N117= | Splice Region (SNP) | VAF 8/95 reads (8%) | catalogued as rs745411054, COSV101282073; called by muse, mutect2
- ERC2 | c.1810C>T p.R604* | Nonsense Mutation (SNP) | VAF 19/143 reads (13%) | catalogued as rs1337394206, COSV99881219; called by muse, mutect2, varscan2
- FLG | c.528C>A p.N176K | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs755044971, COSV100910513; called by muse, mutect2, varscan2
- FPR3 | c.879T>A p.F293L | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.267); catalogued as rs776156120, COSV100200577, COSV59328286; called by muse, mutect2, varscan2
- HEATR6 | c.811T>A p.F271I | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99482113; called by muse, mutect2
- HEPH | c.191C>T p.S64F (on ENST00000343002; = p.S118F on NM_138737.5) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV100294112; called by muse, mutect2, varscan2
- KPNB1 | c.1669C>T p.R557* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as COSV51597673; called by muse, mutect2, varscan2
- LCP2 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1234333977, COSV50453690, COSV50460081; called by muse, mutect2
- LCP2 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.599); catalogued as rs747523987, COSV50447368; called by muse, mutect2
- LHX3 | c.203G>A p.R68H (on ENST00000371748 / NM_178138.6; = p.R73H on NM_014564.5) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs377183234; called by muse, mutect2, varscan2
- LRRN3 | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV100067950, COSV57820688; called by muse, mutect2, varscan2
- MBD3L1 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV99977933; called by muse, mutect2
- MEOX1 | c.345A>T p.E115D | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100233670; called by muse, mutect2, varscan2
- NRXN3 | c.2324A>G p.E775G (on ENST00000335750 / NM_001330195.2; = p.E402G on NM_004796.6) | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100200799; called by muse, mutect2, varscan2
- NSRP1 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs193177731, COSV55935703; called by muse, mutect2, varscan2
- OR5F1 | c.737C>A p.T246K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs377087548, COSV53547607; called by muse, mutect2
- OSR1 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV99693527; called by muse, mutect2, varscan2
- PCF11 | c.3161G>T p.G1054V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV100017783; called by muse, mutect2
- PCNX1 | c.5741G>A p.R1914Q | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749604103, COSV99454063; called by muse, mutect2, varscan2
- PHF8 | c.916C>T p.R306C (on ENST00000357988 / NM_001184896.1; = p.R270C on NM_015107.3) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs782033442, COSV100153799, COSV100153804; called by muse, mutect2
- PIGR | c.2131G>T p.G711* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV100732440, COSV62904853; called by muse, mutect2, varscan2
- PPIG | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs1166424651, COSV53644731; called by muse, mutect2, varscan2
- PRAMEF17 | c.299T>G p.L100R | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99058271; called by muse, mutect2, varscan2
- PRRT2 | c.815C>A p.A272D | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99569227; called by muse, mutect2, varscan2
- PTPRZ1 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV101099552; called by muse, mutect2, varscan2
- PXDN | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs377274038; called by muse, mutect2, varscan2
- RHO | c.825C>G p.I275M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV99960490; called by muse, mutect2, varscan2
- RPS6KA6 | c.2141T>C p.L714P | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV53126358; called by muse, mutect2, varscan2
- SETBP1 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99952034; called by muse, mutect2, varscan2
- SIRPB1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as rs766810178, COSV53539427; called by muse, mutect2, varscan2
- SLIT3 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1272307864, COSV60602365; called by muse, mutect2, varscan2
- STK31 | c.2029A>G p.N677D | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100669124; called by muse, mutect2, varscan2
- TGFBR2 | c.1141A>G p.K381E | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55460724, COSV99846546; called by muse, mutect2, varscan2
- TYR | c.957A>C p.E319D | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.994); catalogued as COSV99633074; called by muse, mutect2, varscan2
- UBE4A | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99347871; called by muse, mutect2
- ZFAT | c.3301G>A p.V1101I | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as rs757186542, COSV64738202; called by muse, mutect2, varscan2
- ZFAT | c.39G>T p.M13I | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100914234; called by muse, mutect2
- ZFP42 | c.806A>T p.H269L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748956140, COSV100478617; called by muse, mutect2, varscan2
- ZNF461 | c.1397A>G p.E466G | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100831356; called by muse, mutect2
- IGHV1OR15-9 | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- MACROH2A2 | c.919_920del p.K307Vfs*32 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel
- OR8G2P | c.168T>A p.H56Q | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.106); called by muse, varscan2
- PDIA4 | c.270-2dup p.X90_splice | Splice Site (INS) | VAF 9/86 reads (10%) | called by mutect2, pindel, varscan2
- TRMT61B | c.582dup p.K195Efs*13 | Frame Shift Ins (INS) | VAF 16/98 reads (16%) | called by mutect2, pindel, varscan2
- TUBA4A | c.158_160del p.F53del | In Frame Del (DEL) | VAF 7/24 reads (29%) | called by pindel, varscan2
- ADCY8 | c.1284G>A p.T428= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs762003224, COSV99650781; called by muse, mutect2
- CDK5RAP2 | c.3537C>T p.Y1179= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs555575334, COSV100575092; called by muse, mutect2, varscan2
- DEFB112 | c.172A>C p.R58= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV100452095; called by muse, mutect2, varscan2
- DIO3 | c.465G>A p.A155= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs540396975, COSV100832047; called by mutect2, varscan2
- DUOX1 | c.2958G>T p.L986= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as COSV100367632; called by muse, mutect2
- EFCAB6 | c.3942G>A p.E1314= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV99412436; called by muse, mutect2, varscan2
- EYA1 | c.1308C>T p.F436= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as COSV58169901; called by muse, mutect2, varscan2
- HAO1 | c.348A>G p.E116= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV101113129, COSV101113233; called by muse, mutect2
- KRT77 | c.624C>A p.T208= | Silent (SNP) | VAF 64/312 reads (21%) | catalogued as rs1049889692, COSV100526922; called by muse, mutect2, varscan2
- LAMA1 | c.288C>A p.P96= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV101055030; called by muse, mutect2, varscan2
- MMRN1 | c.51C>T p.G17= | Silent (SNP) | VAF 11/132 reads (8%) | catalogued as COSV53337508; called by muse, mutect2
- MRGPRX4 | c.630G>A p.P210= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs1438017261, COSV100049634, COSV58591266; called by muse, mutect2, varscan2
- MYH2 | c.1581C>T p.I527= | Silent (SNP) | VAF 22/148 reads (15%) | catalogued as rs1050588952, COSV55432408, COSV55447489; called by muse, varscan2
- NDNF | c.1614C>A p.G538= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV101113090, COSV65633506; called by muse, mutect2
- NOC2L | c.498T>G p.T166= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100497836; called by muse, mutect2, varscan2
- OR2M2 | c.891G>T p.V297= | Silent (SNP) | VAF 28/169 reads (17%) | catalogued as COSV62898280; called by muse, varscan2
- PCDH11X | c.1212C>A p.I404= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV100008322, COSV100009015; called by muse, mutect2, varscan2
- SETD3 | c.204C>T p.S68= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as rs1023276607; called by muse, mutect2, varscan2
- SP100 | c.1146C>A p.P382= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV99892285; called by muse, mutect2, varscan2
- TMEM45A | c.336T>C p.C112= | Silent (SNP) | VAF 33/183 reads (18%) | catalogued as COSV100058114; called by muse, mutect2, varscan2
- TTPAL | c.231C>T p.D77= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs374073244; called by muse, mutect2, varscan2
- USP6 | c.861G>A p.V287= | Silent (SNP) | VAF 26/199 reads (13%) | catalogued as COSV100003015; called by muse, mutect2, varscan2
- ZNF28 | c.2070T>C p.P690= | Silent (SNP) | VAF 16/184 reads (9%) | catalogued as COSV100354269; called by muse, mutect2
- SNORD116-8 | n.64T>C | RNA (SNP) | VAF 34/212 reads (16%) | called by muse, mutect2, varscan2
